TCGA case TCGA-72-4240 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: NCH.
https://portal.gdc.cancer.gov/cases/8f978e47-9ee3-4770-8c7d-95b19b444d5b

Biospecimens (1 sample)
- Sample TCGA-72-4240-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 1; Shortest dimension: 0.1.
